Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6K-01A from TCGA case TCGA-VQ-AA6K, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-VQ-AA6K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e1e7a3c0-a075-4e6e-8845-1a614af0482a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84824c48-61d1-45c4-999f-3e0c7e1677cf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,398; copy number 3: 10,820; copy number 4: 15,919; copy number 5: 9,865; copy number 6: 11,855; copy number 7: 2,175; copy number 8: 214; copy number 9: 1,096; copy number 10: 5; copy number 12: 114; copy number 13: 1; copy number 14: 131; copy number 15: 9; copy number 16: 30; copy number 17: 22; copy number 19: 12; copy number 20: 6; copy number 21: 18; copy number 22: 14; copy number 26: 9; copy number 27: 25; copy number 33: 49; copy number 37: 3; copy number 43: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6K-01A-11D-A40Z-01): tumor purity 0.61, ploidy 1.67, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,569 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr5:38,197,432–40,755,963, 38 genes, copy number 21–43 (within-gene range 4–43): AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4.
- chr5:41,730,065–45,895,970, 71 genes, copy number 12–21 (within-gene range 4–21) (broad region; genes not listed).
- chr11:60,785,333–61,581,148, 43 genes, copy number 14 (within-gene range 2–14): MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138, TMEM216, CPSF7, AP003108.4, AP003108.2, SDHAF2, RN7SL23P, PPP1R32, AP003108.1, MIR4488, LRRC10B, SYT7, AP003108.5, AP003559.1.
- chr11:63,137,867–63,671,921, 17 genes, copy number 12 (within-gene range 2–12): SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9, PLAAT5, AP000484.1, AP001591.1, LGALS12, PLAAT4, PLAAT2, PLAAT3, AP000753.1, ATL3, IMMP1LP1, AP000753.2.
- chr11:63,998,558–64,166,113, 5 genes, copy number 10 (within-gene range 2–10): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr11:66,389,609–67,805,336, 88 genes, copy number 14 (broad region; genes not listed).
- chr11:69,294,151–71,423,423, 47 genes, copy number 13–27: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P.
- chr11:74,012,718–75,742,426, 65 genes, copy number 12–16 (within-gene range 2–16) (broad region; genes not listed).
- chr12:64,264,762–64,390,758, 1 gene, copy number 26 (within-gene range 3–26): C12orf56.
- chr12:64,338,178–64,451,125, 4 genes, copy number 26 (within-gene range 4–26): ATP6V1E1P3, AC135279.1, XPOT, AC135279.2.
- chr12:65,017,468–65,248,355, 6 genes, copy number 20 (within-gene range 3–20): AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:67,065,018–71,118,247, 88 genes, copy number 17–37 (broad region; genes not listed).
- chr19:17,009,189–17,813,576, 49 genes, copy number 9 (within-gene range 2–9): AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3.
- chr20:24,679,547–64,313,132, 969 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
